Somatic mutation profile of tumor specimen 0DX7FM from CCDI case PBCPWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 14.2 years (5,201 days).
Specimen 0DX7FM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e85e4448-9fd9-4afb-8004-bf899f4839be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7ER (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d56998de-38cf-4736-8f05-eb7f4136e834

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 265/1586 reads (17%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MRTFA | c.447G>A p.S149= | Silent (SNP) | VAF 157/1326 reads (12%) | catalogued as rs868058403; called by muse, mutect2, varscan2
- TENM2 | c.3741C>T p.I1247= (on ENST00000518659 / NM_001122679.2; = p.I1015= on NM_001080428.3) | Silent (SNP) | VAF 405/1876 reads (22%) | catalogued as rs376888998; called by muse, mutect2, varscan2
- H3Y1 | c.*3G>A | 3'UTR (SNP) | VAF 90/1422 reads (6%) | called by muse, mutect2
